Somatic mutation profile of cancer-model specimen HCM-CSHL-0512-C24-85N (3D Organoid, passage 4; aliquot HCM-CSHL-0512-C24-85N-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0512-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 76.0 years (27,746 days).
Specimen HCM-CSHL-0512-C24-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88e5382a-7a19-4977-b43c-7ed464e57173.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0512-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0512-C24-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a8574e6-be71-4de0-aae2-814195acfc53

The open-access MAF lists 100 somatic variants for this specimen: 67 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 32, Frame Shift Ins 4, Nonsense Mutation 3, Splice Region 1, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 147/323 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD4 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 204/590 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.009); catalogued as rs779381980, COSV53994167; called by muse, mutect2, varscan2
- ABLIM3 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 167/323 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs376872688; called by muse, mutect2, varscan2
- ADH1B | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs187446108, COSV104396458; called by muse, mutect2, varscan2
- ALMS1 | c.1484C>G p.S495* | Nonsense Mutation (SNP) | VAF 140/261 reads (54%) | catalogued as COSV100042003, COSV52520271; called by muse, mutect2, varscan2
- BAP1 | c.1538C>G p.S513* | Nonsense Mutation (SNP) | VAF 255/255 reads (100%) | catalogued as COSV56229978; called by muse, mutect2, varscan2
- CHUK | c.1519dup p.M507Nfs*17 | Frame Shift Ins (INS) | VAF 44/64 reads (69%) | catalogued as rs1564833034; called by mutect2, pindel, varscan2
- CLIP2 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 244/470 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs1554312777; called by muse, mutect2, varscan2
- CNGB3 | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 122/297 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs753083465, CM122538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.5144G>A p.R1715Q (on ENST00000520002; = p.R1714Q on NM_033225.6) | Missense Mutation (SNP) | VAF 159/159 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs747749324, COSV59310534; called by muse, mutect2, varscan2
- DHRS7 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 199/427 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV53665397; called by muse, mutect2, varscan2
- EGF | c.3124G>A p.V1042M | Missense Mutation (SNP) | VAF 216/485 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs376152924; called by muse, mutect2, varscan2
- ELL | c.22A>G p.R8G | Missense Mutation (SNP) | VAF 249/274 reads (91%) | SIFT tolerated (0.26); PolyPhen benign (0.247); catalogued as rs781430794; called by muse, mutect2, varscan2
- GRIP1 | c.1490T>C p.L497P (on ENST00000359742 / NM_001379345.1; = p.L445P on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 158/1534 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99668079; called by muse, mutect2, varscan2
- KMT2C | c.3420G>A p.M1140I | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs573946244; called by muse, mutect2, varscan2
- MMP19 | c.1271del p.G424Efs*10 | Frame Shift Del (DEL) | VAF 108/1062 reads (10%) | catalogued as COSV59452344; called by mutect2, pindel, varscan2
- OBSL1 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 504/1034 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as rs527421647; called by muse, mutect2
- RBAK | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1400837238; called by muse, mutect2, varscan2
- SH3D19 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 184/379 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as COSV58792566; called by muse, mutect2, varscan2
- SIGLEC5 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 295/664 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs756464645; called by muse, mutect2, varscan2
- SLC2A14 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs766018281, COSV61586599; called by muse, mutect2, varscan2
- SLC39A12 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 137/289 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782725317, COSV101069963, COSV66194871; called by muse, mutect2, varscan2
- TLR1 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58303672; called by muse, mutect2, varscan2
- UBXN1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 252/552 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as rs368902441; called by muse, mutect2, varscan2
- ZNF785 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 224/502 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201848622, COSV67876261; called by muse, mutect2, varscan2
- ADGRV1 | c.4825T>G p.F1609V | Missense Mutation (SNP) | VAF 161/331 reads (49%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ARMC10 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 62/592 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by mutect2, varscan2
- ATP4B | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 227/762 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- C6 | c.2005G>C p.E669Q | Missense Mutation (SNP) | VAF 162/304 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CAMKK2 | c.1011C>G p.F337L | Missense Mutation (SNP) | VAF 270/271 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CFAP61 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 152/287 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CLASP2 | c.2062C>G p.Q688E | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CLDN15 | c.582C>T p.S194= | Splice Region (SNP) | VAF 173/401 reads (43%) | called by muse, mutect2
- DFFB | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 361/716 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- DMBX1 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 263/540 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DOP1A | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EXPH5 | c.3251T>G p.V1084G | Missense Mutation (SNP) | VAF 198/483 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- EXPH5 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 171/323 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FUT10 | c.478C>G p.H160D | Missense Mutation (SNP) | VAF 176/176 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- GAD2 | c.921-1G>C p.X307_splice | Splice Site (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- GALNT15 | c.1132A>T p.N378Y | Missense Mutation (SNP) | VAF 157/338 reads (46%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- GOLGA6L7 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH6 | c.1897A>T p.I633F | Missense Mutation (SNP) | VAF 328/661 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- LRFN4 | c.892dup p.A298Gfs*10 | Frame Shift Ins (INS) | VAF 396/999 reads (40%) | called by mutect2, pindel, varscan2
- LSM5 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LY75 | c.3225G>T p.W1075C | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAN2A2 | c.3272G>A p.G1091D | Missense Mutation (SNP) | VAF 180/387 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- MCF2L2 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 130/306 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- MRPS15 | c.438T>G p.H146Q | Missense Mutation (SNP) | VAF 181/401 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- MYH3 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NDUFS2 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 156/382 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NIN | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 226/475 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR2G3 | c.333A>C p.E111D | Missense Mutation (SNP) | VAF 249/517 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2M7 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 126/303 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR2T11 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 237/482 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.3404C>G p.S1135C | Missense Mutation (SNP) | VAF 152/376 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- PLCL1 | c.3038A>T p.E1013V | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- RASGRF2 | c.3093G>C p.W1031C | Missense Mutation (SNP) | VAF 118/241 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RIMKLB | c.654dup p.R219Tfs*25 | Frame Shift Ins (INS) | VAF 160/387 reads (41%) | called by mutect2, pindel, varscan2
- SHANK3 | c.4759G>A p.A1587T | Missense Mutation (SNP) | VAF 83/1125 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- SPTA1 | c.4828C>T p.Q1610* | Nonsense Mutation (SNP) | VAF 199/444 reads (45%) | called by muse, mutect2, varscan2
- XK | c.119C>G p.T40R | Missense Mutation (SNP) | VAF 291/570 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZAN | c.2270A>T p.E757V | Missense Mutation (SNP) | VAF 231/466 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ZNF461 | c.634dup p.R212Kfs*5 | Frame Shift Ins (INS) | VAF 24/81 reads (30%) | called by mutect2, pindel, varscan2
- ZNF608 | c.3341T>A p.L1114Q | Missense Mutation (SNP) | VAF 276/535 reads (52%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ZNF614 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); called by muse, mutect2
- ZNF835 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 368/721 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- ACSBG1 | c.435C>T p.A145= | Silent (SNP) | VAF 130/295 reads (44%) | catalogued as rs370940723; called by muse, varscan2
- ANO3 | c.702C>T p.C234= | Silent (SNP) | VAF 80/180 reads (44%) | called by muse, varscan2
- BAIAP3 | c.852G>A p.V284= | Silent (SNP) | VAF 191/428 reads (45%) | catalogued as rs1204243439; called by muse, mutect2, varscan2
- BHLHE22 | c.399G>A p.A133= | Silent (SNP) | VAF 474/906 reads (52%) | catalogued as COSV58861182; called by muse, varscan2
- DOT1L | c.2535C>T p.S845= | Silent (SNP) | VAF 261/279 reads (94%) | called by muse, mutect2, varscan2
- DRC1 | c.528C>T p.S176= | Silent (SNP) | VAF 115/249 reads (46%) | catalogued as rs780717600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHB1 | c.1641G>A p.A547= | Silent (SNP) | VAF 176/409 reads (43%) | catalogued as rs776531462, COSV101212909, COSV67670208; called by muse, mutect2, varscan2
- F7 | c.1053C>T p.G351= | Silent (SNP) | VAF 348/713 reads (49%) | catalogued as rs140590804; called by muse, mutect2, varscan2
- FUT10 | c.1011C>T p.I337= | Silent (SNP) | VAF 188/188 reads (100%) | catalogued as COSV59450565; called by muse, mutect2, varscan2
- HTRA2 | c.498C>T p.I166= | Silent (SNP) | VAF 189/395 reads (48%) | catalogued as rs1194234722; called by muse, mutect2, varscan2
- IGSF1 | c.1461C>T p.R487= | Silent (SNP) | VAF 330/659 reads (50%) | catalogued as rs149158944, COSV63840446; called by muse, mutect2, varscan2
- IL12B | c.304C>T p.L102= | Silent (SNP) | VAF 42/428 reads (10%) | catalogued as rs1562113505, COSV99180330; called by muse, mutect2, varscan2
- KCND1 | c.600C>G p.V200= | Silent (SNP) | VAF 336/696 reads (48%) | called by muse, mutect2, varscan2
- LIPE | c.1554C>T p.I518= | Silent (SNP) | VAF 270/523 reads (52%) | catalogued as rs1338293260; called by muse, mutect2, varscan2
- MAMDC4 | c.3618C>T p.V1206= (on ENST00000445819; = p.V1127= on NM_206920.3) | Silent (SNP) | VAF 21/282 reads (7%) | catalogued as rs769920150; called by muse, mutect2
- MLPH | c.567C>T p.L189= | Silent (SNP) | VAF 189/391 reads (48%) | catalogued as COSV52820603; called by muse, mutect2, varscan2
- MRPS27 | c.1170C>A p.I390= | Silent (SNP) | VAF 229/426 reads (54%) | called by muse, mutect2, varscan2
- NALCN | c.2514C>T p.F838= | Silent (SNP) | VAF 239/506 reads (47%) | catalogued as rs200716691; ClinVar: likely benign; called by muse, mutect2, varscan2
- NF1 | c.4503C>T p.D1501= (on ENST00000358273 / NM_001042492.3; = p.D1480= on NM_000267.3) | Silent (SNP) | VAF 114/233 reads (49%) | catalogued as rs577394398; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLCXD2 | c.753G>A p.L251= | Silent (SNP) | VAF 24/548 reads (4%) | catalogued as COSV67340134; called by muse, mutect2
- PYGB | c.1251G>A p.A417= | Silent (SNP) | VAF 187/405 reads (46%) | catalogued as rs767274675; called by muse, mutect2, varscan2
- RYR3 | c.192C>T p.C64= | Silent (SNP) | VAF 165/305 reads (54%) | catalogued as rs769694918, COSV66784372; called by muse, mutect2, varscan2
- SDK1 | c.4980G>A p.T1660= | Silent (SNP) | VAF 15/562 reads (3%) | catalogued as COSV67362316, COSV67383489; called by muse, mutect2
- SIGLEC5 | c.315C>T p.I105= | Silent (SNP) | VAF 143/368 reads (39%) | catalogued as rs1371382400; called by muse, mutect2, varscan2
- SLC4A10 | c.891T>C p.S297= | Silent (SNP) | VAF 171/301 reads (57%) | called by muse, mutect2, varscan2
- TDRD6 | c.168G>A p.T56= | Silent (SNP) | VAF 117/787 reads (15%) | catalogued as COSV100288283; called by muse, mutect2, varscan2
- TMEM271 | c.1077C>T p.P359= | Silent (SNP) | VAF 440/950 reads (46%) | catalogued as rs1170271441; called by muse, mutect2, varscan2
- TMEM271 | c.996C>T p.H332= | Silent (SNP) | VAF 494/1010 reads (49%) | called by muse, mutect2, varscan2
- TSPYL1 | c.540G>C p.L180= | Silent (SNP) | VAF 244/244 reads (100%) | called by muse, mutect2, varscan2
- UPF1 | c.1629G>A p.E543= (on ENST00000599848 / NM_001297549.2; = p.E532= on NM_002911.4) | Silent (SNP) | VAF 357/398 reads (90%) | catalogued as rs1455466301; called by muse, mutect2, varscan2
- WDFY3 | c.8604A>G p.K2868= | Silent (SNP) | VAF 91/202 reads (45%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.2724G>A p.G908= | Silent (SNP) | VAF 507/1423 reads (36%) | catalogued as rs1204223303; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-9546T>G | Intron (SNP) | VAF 146/291 reads (50%) | called by muse, mutect2, varscan2
